TARGET case TARGET-30-PASBYW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/55e030d2-2dd8-5f1b-93bc-0cc647b11e2f

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 2.1 years (771 days); Year of diagnosis: 2008; Days to last follow up: 2,583 days (7.1 years); Cog neuroblastoma risk group: Intermediate Risk; INSS stage: Stage 3.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,583 days (7.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,583; Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASBYW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PASBYW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2583
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.18
- Histology: Favorable
- Diagnostic Category: Ganglioneuroma, maturing subtype OR Ganglioneuroblastoma, well differentiated
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
